Somatic mutation profile of tumor specimen MMRF_1763_1_BM_CD138pos (aliquot MMRF_1763_1_BM_CD138pos_T1_KBS5U_L06440) from MMRF case MMRF_1763, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,498 days).
Specimen MMRF_1763_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 225cc3ce-b495-4add-b981-f694da528421.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1763_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1763_2_PB_Whole_C1_KBS5U_L06493; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5f20ed6-a6cb-40b8-8031-e2740839540d

The open-access MAF lists 107 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 29, Silent 13, Intron 11, 5'UTR 7, RNA 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Splice Region 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/171 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA2D2 | c.2992+7A>G | Splice Region (SNP) | VAF 35/137 reads (26%) | catalogued as rs769360997; called by muse, mutect2, varscan2
- CD33 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV51805473; called by muse, mutect2, varscan2
- COL6A5 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.041); catalogued as rs767890350; called by muse, mutect2, varscan2
- EDEM1 | c.427_429del p.D143del | In Frame Del (DEL) | VAF 94/272 reads (35%) | catalogued as rs780089586; called by mutect2, pindel, varscan2
- EPHA3 | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60722591; called by muse, mutect2, varscan2
- IGHJ5 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 27/28 reads (96%) | PolyPhen benign (0.129); catalogued as rs1296076717; called by muse, mutect2, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, mutect2, varscan2
- IGHV3-33 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as rs746660718; called by muse, varscan2
- KALRN | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1486661865, COSV53773122; called by muse, mutect2, varscan2
- LRRN4 | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV66644309; called by muse, mutect2, varscan2
- MYBPC2 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV63097789; called by muse, mutect2, varscan2
- NCAM2 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs761739899; called by muse, mutect2, varscan2
- PKHD1 | c.10469G>T p.S3490I | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs149486694; called by muse, mutect2, varscan2
- RPL13 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1292954438; called by muse, mutect2, varscan2
- SCART1 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as rs1202631627; called by muse, mutect2, varscan2
- SOCS3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465861203; called by muse, mutect2, varscan2
- SYCN | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs771917628; called by muse, mutect2, varscan2
- TIE1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV65249645; called by muse, mutect2, varscan2
- ZNF608 | c.1999A>G p.N667D | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs765113779; called by muse, mutect2, varscan2
- ADAMTS19 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AKAP12 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANGPTL4 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AQR | c.3155T>A p.L1052Q | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BIRC3 | c.1720C>T p.H574Y | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC180 | c.4609C>T p.P1537S | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CGN | c.2926_2948del p.T976Hfs*36 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- ENAM | c.746_747del p.T249Rfs*10 | Frame Shift Del (DEL) | VAF 110/267 reads (41%) | called by mutect2, pindel, varscan2
- ENDOU | c.972+2T>C p.X324_splice (on ENST00000422538 / NM_001172439.2; = p.X283_splice on NM_006025.4) | Splice Site (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.47-1_48delinsAAT p.X16_splice | Splice Site (TNP) | VAF 5/22 reads (23%) | called by pindel, varscan2*
- NDUFAF5 | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR2B | c.2921C>G p.S974C | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.7775A>G p.D2592G | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PTPRG | c.1983T>A p.D661E | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC63 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SMG5 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- TMEM116 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TOPBP1 | c.3351T>A p.S1117R | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2
- TRAPPC12 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- USP48 | c.2321T>A p.L774H | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- VWA5A | c.1869del p.K623Nfs*43 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- WDR43 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD11 | c.1671A>G p.Q557= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8622C>A p.G2874= | Silent (SNP) | VAF 117/196 reads (60%) | called by muse, mutect2, varscan2
- DDX1 | c.1569G>A p.E523= | Silent (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- DYNLT3 | c.327T>C p.V109= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- EPB41L3 | c.84C>G p.R28= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV59467178; called by muse, mutect2, varscan2
- FAM186A | c.6999T>C p.S2333= | Silent (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- FCAR | c.765G>A p.L255= | Silent (SNP) | VAF 67/257 reads (26%) | called by muse, mutect2, varscan2
- HOXA5 | c.162C>T p.L54= | Silent (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- IGHV3-33 | c.207T>A p.V69= | Silent (SNP) | VAF 89/212 reads (42%) | catalogued as rs752410108; called by muse, varscan2
- SPTBN4 | c.7239A>C p.P2413= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs754059545; called by muse, mutect2, varscan2
- UBE2D2 | c.18C>T p.I6= | Silent (SNP) | VAF 43/159 reads (27%) | called by muse, mutect2, varscan2
- UGGT1 | c.4371T>C p.N1457= | Silent (SNP) | VAF 22/102 reads (22%) | called by mutect2, varscan2
- VEPH1 | c.60C>G p.L20= | Silent (SNP) | VAF 124/378 reads (33%) | catalogued as COSV62875406, COSV62876224; called by muse, mutect2, varscan2
- ABCC8 | c.1333-23C>T | Intron (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- ABLIM3 | c.-87-33G>A | Intron (SNP) | VAF 108/352 reads (31%) | catalogued as rs1048551919; called by muse, mutect2, varscan2
- AC004947.2 | chr7:26535605 A>G | 5'Flank (SNP) | VAF 64/106 reads (60%) | called by muse, mutect2, varscan2
- AP3B2 | c.*211A>G | 3'UTR (SNP) | VAF 54/184 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF34P | n.2557C>T | RNA (SNP) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- CACNG6 | c.*55G>T | 3'UTR (SNP) | VAF 163/558 reads (29%) | called by muse, mutect2, varscan2
- CCND3 | c.*270G>A | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- CDHR3 | c.*1015G>T | 3'UTR (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- CEP170P1 | n.4112_4114del | RNA (DEL) | VAF 28/102 reads (27%) | called by pindel, varscan2
- CERS2 | c.*767T>G | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- CLPX | c.-75C>G | 5'UTR (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- CUL5 | c.*2822T>G | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*2805del | 3'UTR (DEL) | VAF 73/161 reads (45%) | catalogued as rs1256322162; called by mutect2, varscan2
- EPHA4 | c.*56T>A | 3'UTR (SNP) | VAF 99/209 reads (47%) | catalogued as COSV99916332; called by muse, mutect2, varscan2
- FAM122A | c.*2470A>G | 3'UTR (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- FANCM | c.-61T>G | 5'UTR (SNP) | VAF 73/173 reads (42%) | called by muse, mutect2, varscan2
- FASLG | c.*90G>A | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- FKBP15 | c.*4740G>C | 3'UTR (SNP) | VAF 48/74 reads (65%) | called by muse, mutect2, varscan2
- GIN1 | c.*633G>A | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- GREM1 | c.*3289G>A | 3'UTR (SNP) | VAF 36/120 reads (30%) | catalogued as rs1422275483; called by muse, mutect2, varscan2
- GRM8 | c.-216G>A | 5'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- HDHD5-AS1 | n.571C>T | RNA (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- INPP4A | c.*1736C>T | 3'UTR (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- IPMKP1 | n.754C>T | RNA (SNP) | VAF 49/96 reads (51%) | catalogued as rs192018958; called by muse, mutect2, varscan2
- KCNB1 | c.*3563C>T | 3'UTR (SNP) | VAF 4/79 reads (5%) | catalogued as rs1446464269; called by muse, mutect2
- LTB | c.162+138T>A | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- LTB | c.162+38C>G | Intron (SNP) | VAF 42/87 reads (48%) | catalogued as rs749356097, COSV53000787; called by muse, mutect2, varscan2
- LYPLA2 | c.-7G>A | 5'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- MTERF3 | c.-116A>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- MVB12B | c.758-76G>A | Intron (SNP) | VAF 62/180 reads (34%) | catalogued as rs753132361; called by muse, mutect2, varscan2
- NFATC4 | c.*822C>T | 3'UTR (SNP) | VAF 11/66 reads (17%) | catalogued as rs1027198067; called by muse, mutect2, varscan2
- PAX9 | c.*418G>T | 3'UTR (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- PCM1 | c.*214C>T | 3'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as rs1466617567, COSV59586153; called by muse, varscan2
- PDCL | c.*788A>T | 3'UTR (SNP) | VAF 23/36 reads (64%) | catalogued as rs977470092; called by muse, mutect2, varscan2
- PLOD3 | c.*9C>A | 3'UTR (SNP) | VAF 23/142 reads (16%) | catalogued as rs1236205296; called by muse, mutect2, varscan2
- PNLIPRP3 | c.*755G>T | 3'UTR (SNP) | VAF 17/35 reads (49%) | catalogued as rs1310151739; called by muse, mutect2, varscan2
- PPP1R9A | c.*3529A>G | 3'UTR (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- PROCA1 | c.79-66_79-61dup | Intron (INS) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- PSMC6 | c.248-27T>A | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- PTAR1 | c.323+105C>T | Intron (SNP) | VAF 41/51 reads (80%) | catalogued as rs373525825; called by mutect2, varscan2
- RCHY1 | c.*2594A>T | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- RPS6KA2 | c.*256G>A | 3'UTR (SNP) | VAF 37/95 reads (39%) | catalogued as rs763193129; called by muse, mutect2, varscan2
- SLC19A3 | c.-2-655A>G | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2
- SPIN4 | c.*638C>T | 3'UTR (SNP) | VAF 44/46 reads (96%) | catalogued as rs782686008; called by muse, mutect2, varscan2
- SRRM4 | c.*3505C>G | 3'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs1238898856, COSV57417416; called by muse, varscan2
- SUCLA2 | c.90+186C>T | Intron (SNP) | VAF 17/33 reads (52%) | catalogued as rs1376585942; called by muse, mutect2, varscan2
- VGLL3 | c.*8382T>C | 3'UTR (SNP) | VAF 56/178 reads (31%) | catalogued as rs1289230623; called by muse, mutect2, varscan2
- VGLL3 | c.-114A>G | 5'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- WDR6 | c.100+89C>A | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- YY2 | c.*1029G>C | 3'UTR (SNP) | VAF 54/57 reads (95%) | called by muse, mutect2, varscan2
- ZNF331 | c.*159A>T | 3'UTR (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- ZNF716 | c.-50C>A | 5'UTR (SNP) | VAF 98/211 reads (46%) | called by muse, mutect2, varscan2
